Surgical pathology report (de-identified scan), TCGA case TCGA-12-5299, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-5299-01A (Primary Tumor).

Patient: [REDACTED]

AP Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

TCGA-12-5299

CLINICAL HISTORY:

Left parietal brain tumor. MRI [REDACTED]: Conclusions: 1. Compared to [REDACTED], increased size of left parietooccipital mass; 13 mm left-to-right midline shift and mass effect from the left uncus on the left posterior circulation is not significantly different from [REDACTED]. 2. In addition, compared to [REDACTED], there has been increased size of lateral and fourth ventricular dilatation; this may represent obstructing hydrocephalus possibly from lesion in the cervical canal or, alternatively, communicating hydrocephalus possibly secondary to subfalcine herniation and impaired CSF resorption.

GROSS EXAMINATION:

A. "Brain tissue", received fresh for frozen section and transferred to formalin at [REDACTED] is a 4 x 2.6 x 1.6 cm portion of white, tan, and red tissue that is sectioned to reveal a variegated, and focally hemorrhagic anterior. A representative portion was submitted for frozen section as AF1, and the frozen section remnant is submitted entirely in block A1. The remainder of the tissue is submitted in toto in blocks A2-5.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- (representative)- malignant neoplasm consistent with glioblastoma [REDACTED].

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cellular pleomorphism, mitoses, microvascular changes, and pseudopalisading necrosis.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Ordering MD: [REDACTED]

Source: NCI Genomic Data Commons file 4ddde8cf-738a-4261-b0ac-b70f6d4f97e7 (TCGA-12-5299.9F574EF4-3427-4F3C-8493-043A4D08AD00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).